Somatic mutation profile of tumor specimen TCGA-XM-AAZ2-01A (aliquot TCGA-XM-AAZ2-01A-11D-A423-09) from TCGA case TCGA-XM-AAZ2, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 73.5 years (26,861 days).
Specimen TCGA-XM-AAZ2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08d24830-c0e0-4fd1-be0b-cbb73b7a719a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-AAZ2-12A (Buccal Cell Normal), aliquot TCGA-XM-AAZ2-12A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8924e99-32a7-474c-9a36-d0eeb1df1351

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 136/411 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ADAM29 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100821845, COSV100822274; called by muse, mutect2, varscan2
- COL4A1 | c.3749C>T p.P1250L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753887777; called by muse, mutect2, varscan2
- CTSC | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57059365; called by muse, mutect2, varscan2
- ID4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66342939; called by muse, mutect2
- MCC | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs139015770; called by muse, mutect2, varscan2
- SCAF8 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs745485641; called by muse, mutect2, varscan2
- CA5B | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CCDC61 | c.31T>A p.Y11N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CGNL1 | c.2350C>G p.Q784E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2
- CLASP1 | c.2648T>C p.L883P | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GYS1 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBE1 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP002512.3 | c.627C>T p.A209= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99687957; called by muse, mutect2, varscan2
- ART1 | c.870C>T p.C290= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- NR1I2 | c.1107C>T p.F369= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs369188703; called by muse, mutect2, varscan2
- PLXNB2 | c.2949C>G p.P983= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV63784088; called by muse, mutect2, varscan2
- SLC22A4 | c.1251G>T p.L417= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs1484495832; called by muse, mutect2
- WDR77 | c.192C>T p.P64= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV52384922; called by muse, mutect2, varscan2
